Somatic mutation profile of tumor specimen TCGA-SH-A9CT-01A (aliquot TCGA-SH-A9CT-01A-11D-A39R-32) from TCGA case TCGA-SH-A9CT, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.2 years (24,528 days).
Specimen TCGA-SH-A9CT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32f1e2d0-d074-4ac5-be6b-44d55202511e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SH-A9CT-10A (Blood Derived Normal), aliquot TCGA-SH-A9CT-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/61715889-d676-4a3c-a2c6-67cc54dfa74f

The open-access MAF lists 31 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 3, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3B | c.7C>G p.R3G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV54666410; called by muse, mutect2, varscan2
- KDM4B | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1238360670; called by muse, mutect2, varscan2
- OXGR1 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1478656295; called by muse, mutect2, varscan2
- SLC22A3 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs200478210, COSV51709707; called by muse, mutect2, varscan2
- SNRNP200 | c.5368G>A p.E1790K | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV60495460; called by muse, mutect2, varscan2
- STAG3 | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as rs747309208; called by muse, mutect2, varscan2
- C1QTNF8 | c.414C>A p.F138L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CHAC2 | c.414T>G p.S138R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COQ8A | c.995A>G p.E332G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2
- ELF5 | c.357C>A p.Y119* (on ENST00000312319 / NM_198381.2; = p.Y109* on NM_001422.4) | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- FOXO1 | c.1157C>A p.S386* | Nonsense Mutation (SNP) | VAF 43/78 reads (55%) | called by muse, mutect2, varscan2
- GIGYF1 | c.2281T>C p.W761R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MAP3K12 | c.161A>G p.D54G | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYB | c.910T>G p.S304A | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYBL1 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- MYO18B | c.7367_7374del p.S2456Wfs*18 | Frame Shift Del (DEL) | VAF 55/120 reads (46%) | called by mutect2, pindel, varscan2
- PGPEP1 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRPH | c.113C>G p.S38C | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2
- RIMS1 | c.3309T>G p.S1103R | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SVEP1 | c.2315A>C p.E772A | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TFCP2L1 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XRRA1 | c.947T>C p.V316A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- FAM114A2 | c.1428C>T p.L476= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV61078538; called by muse, mutect2, varscan2
- FBN2 | c.6096T>C p.C2032= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs779036257; called by muse, mutect2, varscan2
- GLS2 | c.108C>T p.V36= | Silent (SNP) | VAF 14/30 reads (47%) | called by muse, mutect2, varscan2
- JUN | c.447G>C p.S149= | Silent (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2, varscan2
- OR5D14 | c.462C>T p.G154= | Silent (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- RRM1 | c.465T>C p.Y155= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- TSKS | c.1140G>A p.A380= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs771128278; called by muse, mutect2, varscan2
- ZPBP | c.768C>T p.Y256= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, mutect2, varscan2
- GRM8 | c.727+48365G>A | Intron (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100283236, COSV58863776; called by muse, mutect2, varscan2
